Surgical pathology report (de-identified scan), TCGA case TCGA-38-7271, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site UNC, specimen TCGA-38-7271-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number : [REDACTED]

Diagnosis:

A, B: Lung, right upper lobe lesion, wedge biopsy
- Adenocarcinoma, moderately differentiated, 2.5 cm diameter, consistent with lung primary, without pleural invasion, surgical margins not involved.

Intraoperative Consult Diagnosis:

[REDACTED] n section was requested by Dr. in OR [REDACTED] on [REDACTED] at [REDACTED].

FSA1: Right upper lobe mass, wedge biopsy
- Adenocarcinoma, moderately differentiated
- Defer to special stains to exclude metastasis

Drs. at [REDACTED]

Frozen Section Pathologist:, M.D., PhD.

Clinical History:

The patient is a [REDACTED]-year-old female with a right upper lobe lung mass. CIS: PMHx ([REDACTED] for grade 3, ductal breast [REDACTED] inoma (ER weak, PR negative, HER2 score 0) diagnosed in [REDACTED] reviewed here as OS06-). Positive smoking history prior [REDACTED].

Gross Description:

Received are two appropriately labeled containers.

Container A: Received for frozen section is an 8.0 x 4.5 x 3.0 cm wedge of lung. There is an ill-defined, slightly firm and tan nodule at the resection edge. This measures 2.5 x 1.8 x 0.5 cm. The tissue beneath the stapled tissue is submitted in blocks A1 and A2. Representative sections of the nodule are submitted in blocks A3 and A4. A portion of the nodule is frozen as FSA1.

Container B is additionally labeled "right lung, upper lobe wedge." The specimen is received as a 54.9 gram aggregate of two pieces of lung tissue. The first piece measures 4.3 x 1.7 x 0.9 cm. The larger piece measures 8.5 x 8.0 x 2.9 cm. Blue ink has been applied to the area of previous wedge biopsy. There is an area of defect in between the two pieces, representing the

[page 2 of 2]
initial wedge biopsy. Within the lung tissue, there is a subpleural hard white/firm mass, 3.5 x 3.0 x 3.0 cm in greatest gross dimensions. Sections of normal lung and the large mass were submitted for Tissue procurement. The staple lines are removed and the tissue beneath is submitted in blocks B1 and B2.

B3-B5 - representative sections through tumor

Light Microscopy:

Light microscopic examination is performed by Dr.

The frozen section diagnosis is confirmed.

Sections show a gland-forming carcinoma, without mucinous differentiation. Features favor lung over breast primaries. To clarify lineage, immunohistochemistry was performed, and shows immunoreactivity for TTF-1 and HER2, with no reactivity for GCDFP or ER. This immunophenotype supports lung primary.

Source: NCI Genomic Data Commons file 52a32023-c8ce-48e7-8b0c-8813f93a1e31 (TCGA-38-7271.7EB95F4D-3FB0-4312-89D1-4D5EC9F4F677.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).